Somatic mutation profile of tumor specimen C3L-09061-05 (aliquot CPT0514860006) from CPTAC case C3L-09061, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 45.4 years (16,583 days).
Specimen C3L-09061-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78d0e95c-9680-479d-8f3d-7f9a6c898484.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09061-31 (Blood Derived Normal), aliquot CPT0514970002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1883dd99-4372-496b-abd6-8c80855296aa

The open-access MAF lists 94 somatic variants for this specimen: 61 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 30, Frame Shift Del 1, 3'Flank 1, Splice Region 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF7IP | c.1292A>G p.E431G | Missense Mutation (SNP) | VAF 10/268 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1487567011; called by muse, mutect2
- C1orf226 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV63396369; called by muse, mutect2
- CACNA1H | c.4208C>A p.T1403N | Missense Mutation (SNP) | VAF 26/409 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61984234; called by muse, mutect2
- CCDC50 | c.1400A>G p.H467R (on ENST00000392455 / NM_178335.3; = p.H291R on NM_174908.4) | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0.118); catalogued as rs1192070269; called by muse, mutect2
- CCNA1 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV99715014; called by muse, mutect2
- DCAF12L1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64421454; called by muse, mutect2, varscan2
- DISP2 | c.2831G>A p.R944H | Missense Mutation (SNP) | VAF 36/436 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs1045098882, COSV51116484; called by muse, mutect2
- FLT4 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 26/326 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs771975253; called by muse, mutect2
- GLI3 | c.3029G>A p.R1010Q | Missense Mutation (SNP) | VAF 48/592 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); catalogued as COSV67893869; called by muse, mutect2
- IGHJ1 | c.10T>C p.F4L | Missense Mutation (SNP) | VAF 22/322 reads (7%) | catalogued as rs781831936; called by muse, mutect2
- LRP12 | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 25/406 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); catalogued as rs148476233; called by muse, mutect2
- LRRN1 | c.770T>G p.L257R | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV60013191, COSV60016460; called by muse, mutect2
- MKI67 | c.9520G>A p.G3174R | Missense Mutation (SNP) | VAF 30/360 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs142228417; called by muse, mutect2
- OR10J1 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.768); catalogued as COSV101419893, COSV101420054, COSV71128324; called by muse, mutect2
- OR1N1 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs775766684; called by muse, mutect2
- OR2L8 | c.784A>G p.R262G | Missense Mutation (SNP) | VAF 22/293 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV100594295, COSV61726079; called by muse, mutect2
- OR4C12 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 18/247 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.009); catalogued as COSV58859624, COSV58860140; called by muse, mutect2
- OR4S1 | c.178T>G p.F60V | Missense Mutation (SNP) | VAF 19/358 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1478402299; called by muse, mutect2
- PI15 | c.619T>G p.L207V | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV52644639; called by muse, mutect2
- PRAM1 | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 38/504 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs771127522; called by muse, mutect2
- PROB1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 40/546 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); catalogued as rs1473767147; called by muse, mutect2
- RELT | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 40/606 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs201683616; called by muse, mutect2
- RSPO2 | c.99T>G p.S33R | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.191); catalogued as COSV52641791, COSV99410716; called by muse, mutect2
- SCIMP | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749689759, COSV68311288; called by muse, mutect2
- SOX17 | c.1190C>T p.S397L | Missense Mutation (SNP) | VAF 27/411 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1473687136, COSV52029038; called by muse, mutect2
- SPATA6 | c.1315del p.H439Ifs*59 | Frame Shift Del (DEL) | VAF 22/229 reads (10%) | catalogued as COSV64061896; called by mutect2, pindel
- THAP12 | c.1594C>A p.H532N | Missense Mutation (SNP) | VAF 17/255 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as rs9666739; called by muse, mutect2
- TRIM64 | c.1215A>C p.Q405H | Missense Mutation (SNP) | VAF 28/462 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV59839961; called by muse, mutect2
- ZNF274 | c.1240A>G p.T414A (on ENST00000610905; = p.T309A on NM_016324.3) | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs747641307; called by muse, mutect2, varscan2
- ZNF382 | c.1412A>C p.K471T | Missense Mutation (SNP) | VAF 21/289 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99497239; called by muse, mutect2
- ZNF536 | c.3292G>T p.G1098C | Missense Mutation (SNP) | VAF 32/435 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.342); catalogued as COSV62827646, COSV62833574; called by muse, mutect2
- ZNF671 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.072); catalogued as COSV58052205; called by muse, mutect2
- ATP11B | c.3280G>C p.D1094H | Missense Mutation (SNP) | VAF 26/224 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.142); called by muse, mutect2
- CD163L1 | c.940T>G p.L314V | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.02); called by muse, mutect2
- CLEC3A | c.110A>C p.K37T (on ENST00000651443; = p.K28T on NM_005752.6) | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, mutect2
- FAM135B | c.26A>G p.E9G | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FAT2 | c.535C>A p.Q179K | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.174); called by muse, mutect2
- HEATR3 | c.758T>C p.V253A | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2
- LRP1B | c.5661A>C p.E1887D | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- LYPD1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.415); called by muse, mutect2
- MAP2 | c.278G>A p.R93K | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- NR1H2 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 17/363 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- NRXN3 | c.803G>C p.C268S | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.965); called by muse, mutect2
- OR10J3 | c.323T>A p.F108Y | Missense Mutation (SNP) | VAF 38/356 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); called by muse, mutect2
- OR14A16 | c.914A>C p.K305T | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.028); called by muse, mutect2
- OR51B4 | c.439A>C p.M147L | Missense Mutation (SNP) | VAF 22/282 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- PCDHGB4 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 18/323 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PON3 | c.880A>T p.N294Y | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2
- SALL3 | c.209A>G p.Q70R | Missense Mutation (SNP) | VAF 51/564 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- SAMD9 | c.42G>C p.W14C | Missense Mutation (SNP) | VAF 24/269 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SCN10A | c.3883T>G p.F1295V | Missense Mutation (SNP) | VAF 35/388 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SNCAIP | c.1356A>C p.E452D | Missense Mutation (SNP) | VAF 15/304 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- SPEG | c.2858G>A p.C953Y | Missense Mutation (SNP) | VAF 23/287 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SSTR5 | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 38/586 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SULT1A2 | c.274+7G>T | Splice Region (SNP) | VAF 22/544 reads (4%) | called by muse, mutect2
- TIAM1 | c.3047A>G p.D1016G | Missense Mutation (SNP) | VAF 33/426 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.026); called by muse, mutect2
- TRIP12 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2
- TTN | c.89488A>C p.T29830P (on ENST00000591111; = p.T22406P on NM_003319.4) | Missense Mutation (SNP) | VAF 18/316 reads (6%) | PolyPhen benign (0.369); called by muse, mutect2
- TTN | c.76703A>G p.K25568R (on ENST00000591111; = p.K18144R on NM_003319.4) | Missense Mutation (SNP) | VAF 22/328 reads (7%) | PolyPhen benign (0.003); called by muse, mutect2
- UBA2 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2
- ZBTB17 | c.420G>T p.E140D | Missense Mutation (SNP) | VAF 15/371 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- ABCA3 | c.2310G>A p.P770= | Silent (SNP) | VAF 46/436 reads (11%) | catalogued as rs376037988; called by muse, mutect2, varscan2
- AGBL1 | c.1239T>G p.T413= | Silent (SNP) | VAF 30/380 reads (8%) | catalogued as COSV101224073; called by muse, mutect2
- CCN4 | c.447C>T p.G149= | Silent (SNP) | VAF 40/608 reads (7%) | catalogued as rs530441446, COSV51530033; called by muse, mutect2
- DCSTAMP | c.1062T>G p.S354= | Silent (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- DNM2 | c.2418G>A p.A806= (on ENST00000355667 / NM_001005360.3; = p.A802= on NM_004945.3) | Silent (SNP) | VAF 34/520 reads (7%) | catalogued as rs200968756, COSV53033988; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2
- DPP10 | c.2379A>G p.E793= | Silent (SNP) | VAF 10/209 reads (5%) | called by muse, mutect2
- FCHSD2 | c.1971G>A p.P657= | Silent (SNP) | VAF 28/404 reads (7%) | catalogued as rs139161872; called by muse, mutect2
- FERD3L | c.327C>T p.R109= | Silent (SNP) | VAF 31/480 reads (6%) | catalogued as COSV51763615; called by muse, mutect2
- ISM1 | c.186T>C p.S62= | Silent (SNP) | VAF 34/386 reads (9%) | catalogued as rs1256824910; called by muse, mutect2
- KCND2 | c.1560T>C p.S520= | Silent (SNP) | VAF 13/283 reads (5%) | called by muse, mutect2
- KLHL29 | c.1497G>A p.E499= | Silent (SNP) | VAF 26/390 reads (7%) | called by muse, mutect2
- LINGO3 | c.1272C>T p.D424= | Silent (SNP) | VAF 42/606 reads (7%) | catalogued as rs1237162448; called by muse, mutect2
- LRP1B | c.1575C>G p.L525= | Silent (SNP) | VAF 10/205 reads (5%) | catalogued as COSV67275027; called by muse, mutect2
- MIDN | c.291C>G p.T97= | Silent (SNP) | VAF 29/400 reads (7%) | called by muse, mutect2
- MTX2 | c.495C>A p.V165= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as rs1324094468; called by muse, mutect2
- NLGN1 | c.2280A>T p.P760= | Silent (SNP) | VAF 26/367 reads (7%) | called by muse, mutect2
- OR13G1 | c.780T>G p.A260= | Silent (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- OR5M10 | c.43T>C p.L15= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- PAICS | c.762G>A p.E254= | Silent (SNP) | VAF 19/258 reads (7%) | called by muse, mutect2
- PRPF38B | c.712A>C p.R238= | Silent (SNP) | VAF 20/305 reads (7%) | catalogued as COSV64223605; called by muse, mutect2
- RAF1 | c.333C>T p.R111= | Silent (SNP) | VAF 8/222 reads (4%) | called by muse, mutect2
- SLC25A31 | c.255C>A p.G85= | Silent (SNP) | VAF 16/236 reads (7%) | called by muse, mutect2
- SLCO5A1 | c.2487A>T p.I829= | Silent (SNP) | VAF 26/390 reads (7%) | called by muse, mutect2
- TACC2 | c.8193C>T p.T2731= (on ENST00000334433; = p.T809= on NM_006997.4) | Silent (SNP) | VAF 29/344 reads (8%) | catalogued as rs762281778; called by muse, mutect2
- THEMIS | c.309G>A p.R103= | Silent (SNP) | VAF 15/295 reads (5%) | catalogued as rs1287422597, COSV64072048; called by muse, mutect2
- TLL1 | c.432A>G p.R144= | Silent (SNP) | VAF 19/350 reads (5%) | called by muse, mutect2
- TRPC7 | c.477G>A p.T159= | Silent (SNP) | VAF 18/470 reads (4%) | catalogued as rs1373580789; called by muse, mutect2
- XIRP2 | c.243G>A p.V81= | Silent (SNP) | VAF 25/414 reads (6%) | catalogued as COSV54709265; called by muse, mutect2
- ZNF282 | c.1347C>T p.D449= | Silent (SNP) | VAF 36/531 reads (7%) | called by muse, mutect2
- ZNF528 | c.972T>G p.P324= | Silent (SNP) | VAF 14/393 reads (4%) | called by muse, mutect2
- KLRF2 | chr12:9898929 A>C | 3'Flank (SNP) | VAF 26/362 reads (7%) | catalogued as COSV100334834; called by muse, mutect2
- LDLRAD4 | c.182-8400C>T | Intron (SNP) | VAF 16/254 reads (6%) | called by muse, mutect2
- MAGEE2 | c.*1A>G | 3'UTR (SNP) | VAF 20/120 reads (17%) | catalogued as COSV100972980; called by muse, mutect2, varscan2
